Somatic mutation profile of tumor specimen TCGA-GR-A4D6-01A (aliquot TCGA-GR-A4D6-01A-11D-A31X-10) from TCGA case TCGA-GR-A4D6, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 54.3 years (19,838 days).
Specimen TCGA-GR-A4D6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cbde8d1-a297-4d53-8b16-9bd9a5568bc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GR-A4D6-10A (Blood Derived Normal), aliquot TCGA-GR-A4D6-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/269cf9ef-29f4-4629-b082-a9bc7884403b

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 28, Silent 16, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VWF | c.7390C>T p.R2464C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs61751286, CM070317, COSV54626153; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMN1 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV99861662; called by muse, mutect2, varscan2
- ANKRD11 | c.5722C>T p.P1908S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.355); catalogued as rs781644006, COSV99970408; called by muse, mutect2, varscan2
- ANO4 | c.1237T>G p.C413G (on ENST00000392977 / NM_001286615.2; = p.C378G on NM_178826.4) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100153600; called by muse, mutect2, varscan2
- ATP2B4 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759843418, COSV58183905; called by muse, varscan2
- BIRC7 | c.881G>A p.R294H (on ENST00000217169 / NM_139317.3; = p.R276H on NM_022161.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs142521563; called by muse, mutect2, varscan2
- CASR | c.1916G>A p.R639H (on ENST00000490131; = p.R716H on NM_000388.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs201670662, CM119395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS6 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779475869, COSV59831890, COSV59833518; called by muse, mutect2, varscan2
- CNTRL | c.6748G>A p.A2250T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1317469000, COSV53050430; called by muse, mutect2, varscan2
- COL24A1 | c.4230A>C p.E1410D | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as COSV65302287; called by muse, mutect2, varscan2
- CRYGN | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100484810; called by muse, mutect2, varscan2
- EP300 | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs775703248, COSV99609584; called by muse, mutect2, varscan2
- H1-3 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.09); catalogued as COSV99768870; called by muse, mutect2, varscan2
- ITPRID2 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1234770830, COSV100238667; called by mutect2, varscan2
- JUNB | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.066); catalogued as COSV100040318; called by muse, mutect2, varscan2
- KIF13A | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV99437811; called by muse, mutect2, varscan2
- KLHL6 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100384984; called by muse, mutect2, varscan2
- LRFN5 | c.472A>C p.N158H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53250929, COSV99985198; called by mutect2, varscan2
- MAF | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.417); catalogued as COSV100391968; called by muse, mutect2, varscan2
- MDGA2 | c.2386G>A p.D796N (on ENST00000399232 / NM_001113498.2; = p.D498N on NM_182830.4) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100638202; called by muse, mutect2, varscan2
- NFKBIE | c.1322T>C p.L441P (on ENST00000275015; = p.L302P on NM_004556.3) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99241375; called by muse, mutect2, varscan2
- PLD1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs771670632, COSV60565942; called by muse, mutect2, varscan2
- PLXDC2 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as rs372842489, COSV101023230; called by muse, mutect2, varscan2
- PODN | c.1222C>T p.R408W (on ENST00000395871; = p.R360W on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100439780; called by muse, mutect2, varscan2
- PPP2R5A | c.1286T>G p.L429R | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99806900; called by muse, mutect2, varscan2
- PTPRK | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758842627, COSV100949694; called by muse, mutect2
- ROBO1 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101459192; called by muse, mutect2, varscan2
- SHANK2 | c.2439+1G>A p.X813_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV53586706; called by muse, mutect2
- SYNRG | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.295); catalogued as rs753930749; called by muse, mutect2, varscan2
- TENM1 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100950723; called by muse, mutect2, varscan2
- TTN | c.11107T>A p.S3703T (on ENST00000591111; = p.S3657T on NM_003319.4) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs1323824714, COSV100626651; called by muse, mutect2, varscan2
- CCDC189 | c.714A>G p.P238= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100079791; called by muse, mutect2, varscan2
- CDH4 | c.2454C>T p.R818= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs199908722, COSV64676163; called by mutect2, varscan2
- CNN2 | c.795C>G p.G265= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV54023280, COSV99566526; called by muse, mutect2, varscan2
- FCRL3 | c.24G>A p.L8= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as COSV100943488; called by muse, mutect2, varscan2
- H2BC8 | c.108G>A p.E36= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs1435961364, COSV99773352; called by muse, varscan2
- H2BC8 | c.45C>T p.S15= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs143774290; called by muse, varscan2
- HCFC1 | c.4950C>T p.G1650= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100129761; called by muse, mutect2, varscan2
- IGSF11 | c.360C>T p.C120= (on ENST00000393775 / NM_001015887.3; = p.C119= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs779094816, COSV61180680; called by muse, mutect2, varscan2
- INSR | c.1050G>A p.S350= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs751541632, COSV100253243; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEF1 | c.51G>A p.G17= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs1212920151, COSV100511035; called by muse, mutect2, varscan2
- MYO18B | c.3507C>T p.A1169= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs375428629; called by muse, mutect2, varscan2
- POU3F2 | c.759C>T p.G253= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100099430; called by muse, mutect2
- RARB | c.510G>A p.S170= (on ENST00000383772 / NM_001290216.2; = p.S163= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs761412606, COSV100412796; called by muse, mutect2, varscan2
- RGS6 | c.1386C>A p.G462= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1178417556, COSV100666904; called by muse, mutect2, varscan2
- RTL3 | c.708C>T p.F236= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV58186020; called by mutect2, varscan2
- SORCS3 | c.2052G>T p.V684= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100863765; called by mutect2, varscan2
